Somatic mutation profile of tumor specimen TCGA-V9-A7HT-01A (aliquot TCGA-V9-A7HT-01A-11D-A33Q-10) from TCGA case TCGA-V9-A7HT, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.4 years (24,610 days).
Specimen TCGA-V9-A7HT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92a606d2-e020-4846-8f78-fb88e1df65cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V9-A7HT-10A (Blood Derived Normal), aliquot TCGA-V9-A7HT-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eb4c8c4-66e9-4734-86e1-93166e356abe

The open-access MAF lists 83 somatic variants for this specimen: 65 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Frame Shift Ins 5, Frame Shift Del 4, In Frame Del 3, 3'UTR 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRM | c.77T>A p.V26D | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101126045; called by muse, mutect2, varscan2
- AFDN | c.3464A>G p.K1155R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.132); catalogued as COSV100652278, COSV60042811; called by muse, mutect2, varscan2
- AKAP12 | c.4509G>T p.E1503D | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99482155; called by muse, mutect2, varscan2
- ANKRD12 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100040516; called by muse, mutect2, varscan2
- ARHGAP30 | c.2173_2175del p.K725del | In Frame Del (DEL) | VAF 12/92 reads (13%) | catalogued as rs752827763; called by pindel, varscan2
- ATP5F1A | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs771547673, COSV56361932; called by muse, mutect2
- BRPF1 | c.3433G>C p.V1145L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV100115000, COSV100115154; called by muse, mutect2, varscan2
- C20orf85 | c.194T>A p.I65N | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV100959341; called by muse, mutect2, varscan2
- CCDC136 | c.2663A>T p.Q888L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); catalogued as COSV99921918; called by muse, mutect2, varscan2
- CDH3 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99867194; called by muse, mutect2, varscan2
- DPEP3 | c.606C>G p.D202E | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV99262517; called by muse, mutect2, varscan2
- ELMO2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.59); catalogued as rs924016543, COSV51682599; called by muse, mutect2
- EPHA2 | c.208T>C p.C70R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625980; called by muse, mutect2, varscan2
- FGL2 | c.752G>C p.W251S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369050689, COSV99591979; called by muse, mutect2, varscan2
- HCRTR2 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV100904045; called by muse, mutect2, varscan2
- IFIT1B | c.1204T>C p.Y402H | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879019; called by muse, mutect2, varscan2
- IQUB | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.086); catalogued as COSV100226617; called by muse, mutect2, varscan2
- KANSL2 | c.834G>T p.L278F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV100770794; called by muse, mutect2, varscan2
- KCNH2 | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs199473506, CM097340, COSV100058768; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- KHDRBS2 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1432676329, COSV55494830; called by muse, mutect2, varscan2
- KLHDC10 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100110801; called by muse, mutect2, varscan2
- KMT2C | c.6523A>G p.S2175G | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100064548; called by muse, mutect2, varscan2
- LRP8 | c.2869C>T p.L957F | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); catalogued as COSV100035894; called by muse, mutect2, varscan2
- LRRC37A2 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs540928862, COSV100238557; called by mutect2, varscan2
- MEGF8 | c.7483G>A p.V2495M (on ENST00000251268 / NM_001271938.2; = p.V2428M on NM_001410.3) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376078071; called by muse, mutect2, varscan2
- MORC4 | c.240T>G p.N80K | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99716671; called by muse, mutect2, varscan2
- MUC16 | c.5323A>G p.T1775A | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV101197348; called by muse, mutect2, varscan2
- NEFL | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99647778; called by muse, mutect2, varscan2
- NEO1 | c.328_329insA p.F110Yfs*12 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | catalogued as COSV99981055; called by mutect2, pindel, varscan2
- NOS1 | c.4135G>A p.A1379T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100499822; called by muse, mutect2, varscan2
- NPC1 | c.3181A>C p.I1061L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV99339774; called by muse, mutect2, varscan2
- OR52R1 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100617554; called by muse, mutect2, varscan2
- PCDHGB3 | c.2347G>T p.D783Y | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99528149; called by muse, mutect2, varscan2
- PDXDC1 | c.2152A>G p.S718G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV99816729; called by muse, mutect2, varscan2
- PPP1R14B | c.85T>A p.Y29N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV99657027; called by muse, mutect2, varscan2
- PRMT5 | c.1073T>A p.V358D | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV99362702; called by muse, mutect2, varscan2
- PRMT7 | c.684T>G p.I228M | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.387); catalogued as COSV100266555; called by muse, mutect2, varscan2
- PTPRD | c.4995T>G p.N1665K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV100642438; called by muse, mutect2, varscan2
- RALGAPA1 | c.4234C>G p.H1412D | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV99352748; called by muse, mutect2, varscan2
- RASGRP4 | c.644G>C p.R215P | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99498337; called by muse, mutect2, varscan2
- SHQ1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV100344385; called by muse, mutect2, varscan2
- SPAG5 | c.2852G>C p.R951P | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs546549488, COSV56885955, COSV99881681; called by muse, mutect2, varscan2
- SRPK2 | c.899A>C p.K300T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.201); catalogued as COSV100623685; called by muse, mutect2, varscan2
- TASOR2 | c.3350G>T p.G1117V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV100049828; called by muse, mutect2, varscan2
- TNRC6C | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV100049286; called by muse, mutect2
- TTN | c.55418C>A p.T18473N (on ENST00000591111; = p.T11049N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | PolyPhen benign (0.107); catalogued as COSV100588798, COSV60311893; called by muse, mutect2, varscan2
- UBR5 | c.8203T>A p.S2735T | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV99638883; called by muse, mutect2, varscan2
- UGT1A3 | c.818T>C p.M273T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.353); catalogued as COSV100529229; called by muse, mutect2, varscan2
- XPO5 | c.2666G>C p.R889T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99540192; called by muse, mutect2, varscan2
- ZNF830 | c.589T>A p.S197T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100030334; called by muse, mutect2, varscan2
- ZNF830 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100030335; called by muse, mutect2, varscan2
- ZNHIT6 | c.943A>T p.R315W | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100995430; called by muse, mutect2, varscan2
- ZNRF1 | c.503C>G p.P168R | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100096514; called by muse, mutect2, varscan2
- ARHGAP32 | c.2167_2169del p.F723del (on ENST00000310343 / NM_001378025.1; = p.F374del on NM_014715.4) | In Frame Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.2988del p.E997Rfs*22 | Frame Shift Del (DEL) | VAF 92/250 reads (37%) | called by mutect2, pindel, varscan2
- COL2A1 | c.4111G>A p.A1371T | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- DNM3 | c.282del p.F94Lfs*15 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- FANCA | c.2629_2637dup p.S877_A879dup | In Frame Ins (INS) | VAF 14/71 reads (20%) | called by mutect2, varscan2
- GTF3C3 | c.1042del p.I348* | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- LRP2 | c.8358dup p.M2787Yfs*4 | Frame Shift Ins (INS) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- MYSM1 | c.1493_1494delinsA p.M498Nfs*21 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | called by pindel, varscan2*
- NEK10 | c.991dup p.W331Lfs*20 | Frame Shift Ins (INS) | VAF 30/110 reads (27%) | called by mutect2, pindel, varscan2
- P2RY4 | c.544_546del p.T182del | In Frame Del (DEL) | VAF 24/47 reads (51%) | called by pindel, varscan2
- PSIP1 | c.805dup p.V269Gfs*8 | Frame Shift Ins (INS) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- TTN | c.99057dup p.E33020* (on ENST00000591111; = p.E25596* on NM_003319.4) | Frame Shift Ins (INS) | VAF 15/121 reads (12%) | called by mutect2, pindel, varscan2
- AGAP1 | c.1080G>A p.S360= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs776690991, COSV100363366; called by muse, varscan2
- BABAM1 | c.825T>C p.G275= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV100845686; called by muse, mutect2
- BAMBI | c.342T>C p.S114= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100977472; called by muse, mutect2, varscan2
- BCR | c.3207C>T p.Y1069= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs138762891; called by muse, mutect2, varscan2
- CRTC3 | c.1035C>T p.S345= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV99185599; called by muse, mutect2, varscan2
- CWF19L1 | c.1281T>G p.S427= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100821420; called by muse, mutect2, varscan2
- FCRL6 | c.216A>T p.A72= | Silent (SNP) | VAF 37/189 reads (20%) | catalogued as COSV100219967; called by muse, mutect2, varscan2
- IQCN | c.1026A>T p.T342= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV101148206; called by muse, mutect2, varscan2
- MCF2L2 | c.1218G>A p.R406= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs771013741, COSV100190772; called by muse, mutect2, varscan2
- OR10G2 | c.195C>T p.Y65= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as rs1363463435, COSV101606927; called by muse, mutect2, varscan2
- POLR2J3 | c.15A>C p.P5= | Silent (SNP) | VAF 39/644 reads (6%) | called by muse, mutect2
- SLIT2 | c.213G>C p.T71= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV99879745; called by muse, mutect2, varscan2
- SNCAIP | c.1554G>T p.L518= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99746568; called by muse, mutect2, varscan2
- SULF1 | c.1203C>T p.N401= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV99481688; called by muse, mutect2, varscan2
- UTRN | c.4212C>A p.T1404= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV100839375; called by muse, mutect2, varscan2
- ZNF782 | c.1110A>G p.E370= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV100001047; called by muse, mutect2, varscan2
- ACAT2 | c.-2A>C | 5'UTR (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100887088; called by muse, mutect2
- EML4 | c.*42G>A | 3'UTR (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100580571; called by muse, mutect2, varscan2
